Somatic mutation profile of cancer-model specimen HCM-BROD-0957-C34-85A (3D Organoid, passage 8; aliquot HCM-BROD-0957-C34-85A-01D-A881-36), derived from the metastatic tumor of HCMI case HCM-BROD-0957-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: GX; Age at diagnosis: 42.7 years (15,582 days).
Specimen HCM-BROD-0957-C34-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e565846-146d-4bf4-8c2c-eb0582a521b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0957-C34-10A (Blood Derived Normal), aliquot HCM-BROD-0957-C34-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38051c57-b59e-4b56-85b5-1cf458e655ce

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 13, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCD2 | c.391A>C p.I131L | Missense Mutation (SNP) | VAF 32/487 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.048); catalogued as rs974040132; called by muse, mutect2
- MLST8 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 26/476 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV57029336; called by muse, mutect2
- MUC17 | c.2347G>A p.E783K | Missense Mutation (SNP) | VAF 31/884 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV60280441; called by muse, mutect2
- SLC7A6OS | c.351C>A p.S117R | Missense Mutation (SNP) | VAF 146/766 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.068); catalogued as COSV99862305; called by muse, mutect2, varscan2
- VAMP7 | c.107T>C p.I36T | Missense Mutation (SNP) | VAF 30/451 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); catalogued as rs777066855; called by muse, mutect2
- VPS39 | c.1399T>G p.C467G (on ENST00000348544 / NM_001301138.2; = p.C456G on NM_015289.5) | Missense Mutation (SNP) | VAF 54/221 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs944479488; called by muse, mutect2, varscan2
- ADRA2C | c.116G>T p.W39L | Missense Mutation (SNP) | VAF 58/732 reads (8%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2
- DOCK11 | c.3642T>A p.S1214R | Missense Mutation (SNP) | VAF 60/164 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- GFI1 | c.328G>C p.D110H | Missense Mutation (SNP) | VAF 19/278 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- H4C12 | c.88A>G p.I30V | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- KL | c.2542G>C p.V848L | Missense Mutation (SNP) | VAF 135/169 reads (80%) | SIFT tolerated (0.13); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- MPP2 | c.697G>A p.G233S (on ENST00000461854 / NM_001278372.2; = p.G209S on NM_005374.5) | Missense Mutation (SNP) | VAF 36/536 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); called by muse, mutect2
- WWP1 | c.2080A>G p.K694E | Missense Mutation (SNP) | VAF 17/360 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); called by muse, mutect2
- HSPA12B | c.447C>T p.S149= | Silent (SNP) | VAF 47/154 reads (31%) | called by muse, mutect2, varscan2
- KCTD8 | c.555C>T p.A185= | Silent (SNP) | VAF 19/446 reads (4%) | catalogued as rs927735520; called by muse, mutect2
- PADI3 | c.1794C>T p.G598= | Silent (SNP) | VAF 17/293 reads (6%) | called by muse, mutect2
